MMRF case MMRF_1223 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c0f183ec-c116-43e6-98d1-f6129c37cd0d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 35 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 35.7 years (13,027 days); ISS stage: III; Days to last known disease status: 1,629 days (4.5 years); Days to last follow up: 1,629 days (4.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 508 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 606 days (1.7 years); Days to treatment end: 606 days (1.7 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 606 days (1.7 years); Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 742 days (2.0 years); Days to treatment end: 839 days (2.3 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 942 days (2.6 years); Days to treatment end: 1,453 days (4.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,476 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,481 days (4.1 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,509 days (4.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,629.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 4 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2450 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.055 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 19 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 13.5 ×10⁹/L; Absolute Neutrophil 11.1 ×10⁹/L; Platelets 400 ×10⁹/L; Creatinine 301 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.33 mmol/L; Albumin 48 g/L; Total Protein 7.3 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 88 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.054 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.49 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 176 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 3.47 mmol/L.
- Day 174 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.615 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 183 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.5 mmol/L; Albumin 51 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 278 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.467 mg/dL; Immunoglobulin G 3.65 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 3.22 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.1 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.07 mmol/L.
- Day 334 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 213 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 426 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 3.93 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 189 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 508 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 8.63 g/L; Immunoglobulin A 3.5 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.57 mmol/L.
- Day 593 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.83 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 3.52 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 4.84 mmol/L.
- Day 700 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 5.92 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 788 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 3.96 mmol/L.
- Day 839 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.062 mg/dL; Immunoglobulin G 2.53 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 14.3 ×10⁹/L; Absolute Neutrophil 12.5 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 272 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.
- Day 935 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 71.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.775 mg/dL; Immunoglobulin G 2.99 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 6.22 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 382 ×10⁹/L; Creatinine 196 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.02 mmol/L.
- Day 1,026 (ECOG 0): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.053 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.956 mg/dL; Immunoglobulin G 3.15 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 1,166 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.866 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.822 mg/dL; Immunoglobulin G 2.74 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 234 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.58 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 1,257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.704 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.879 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 382 ×10⁹/L; Creatinine 196 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 8.31 mmol/L.
- Day 1,341 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.741 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.962 mg/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 350 ×10⁹/L; Creatinine 199 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 1,425 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 3.38 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6 g/dL; Glucose 7.04 mmol/L.
- Day 1,481 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.978 mg/dL; Immunoglobulin G 6.1 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 189 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 7.59 mmol/L.
- Day 1,628 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.526 mg/dL; Immunoglobulin G 2.47 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 261 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.03 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 4: Weight: 70 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample MMRF_1223_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 593 days (1.6 years).
- Sample MMRF_1223_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 593 days (1.6 years).
- Sample MMRF_1223_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 700 days (1.9 years).
- Sample MMRF_1223_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 935 days (2.6 years).
